Somatic mutation profile of tumor specimen TCGA-IR-A3LB-01A (aliquot TCGA-IR-A3LB-01A-11D-A243-09) from TCGA case TCGA-IR-A3LB, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 53.0 years (19,374 days).
Specimen TCGA-IR-A3LB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ebdeecdd-a368-499e-a563-4b15fd10466b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IR-A3LB-10A (Blood Derived Normal), aliquot TCGA-IR-A3LB-10A-01D-A243-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a6ecb00-b89a-46f9-98fe-c1e91a250f56

The open-access MAF lists 53 somatic variants for this specimen: 40 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 35, Silent 13, Nonsense Mutation 3, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRF1 | c.2713C>G p.Q905E | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV51945265, COSV51948248; called by muse, varscan2
- ADPGK | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV61175401; called by muse, mutect2, varscan2
- ANKS1B | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.165); catalogued as rs377459874; called by muse, mutect2, varscan2
- ARNT | c.2167G>A p.V723M | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1233643056, COSV55014194, COSV99649081; called by muse, mutect2, varscan2
- ASTN2 | c.2483T>A p.V828D (on ENST00000313400 / NM_001365069.1; = p.V777D on NM_014010.5) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.914); catalogued as COSV57823148; called by muse, mutect2, varscan2
- CALB1 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.048); catalogued as COSV55369998; called by muse, mutect2
- CEP19 | c.233G>C p.R78P | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); catalogued as rs201883289, COSV56361604, COSV99582269; called by muse, mutect2, varscan2
- CPSF4 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as rs766880581, COSV52859714; called by muse, mutect2
- DOLK | c.1057A>G p.I353V | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV58282975; called by muse, mutect2, varscan2
- EHBP1L1 | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0.203); catalogued as COSV58575468; called by muse, mutect2, varscan2
- EHBP1L1 | c.1517G>C p.R506T | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV58575476; called by muse, mutect2, varscan2
- FAT4 | c.7579G>A p.A2527T | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs201007539, COSV58687043; called by muse, mutect2, varscan2
- FEM1B | c.599T>G p.I200R | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV60989936; called by muse, mutect2, varscan2
- GDF6 | c.1204A>C p.I402L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1404630168, COSV54628495; called by muse, mutect2, varscan2
- GOLGA8G | c.1189G>A p.V397I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.09); catalogued as rs1338892121, COSV100284606; called by mutect2, varscan2
- HASPIN | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); catalogued as COSV54001026; called by muse, mutect2, varscan2
- JMY | c.1565G>A p.R522Q | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as rs531886847, COSV68661095; called by muse, mutect2, varscan2
- KAZN | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs1334887049, COSV65726633; called by muse, mutect2, varscan2
- KMT2D | c.613C>A p.L205I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.492); catalogued as COSV56493465; called by muse, mutect2
- MANEAL | c.1270C>T p.R424C (on ENST00000373045 / NM_001113482.1; = p.R202C on NM_152496.2) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); catalogued as rs200095743, COSV61116104; called by muse, mutect2, varscan2
- MELTF | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as rs750544772, COSV99585988; called by muse, varscan2
- NFXL1 | c.2613C>A p.N871K | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67433084; called by mutect2, varscan2
- PCDHGA11 | c.1871C>T p.T624M | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53934490; called by muse, mutect2, varscan2
- PNLDC1 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.608); catalogued as rs143586629; called by muse, mutect2, varscan2
- POTEE | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58246280; called by muse, mutect2, varscan2
- RBPJL | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.376); catalogued as COSV100636947; called by muse, mutect2, varscan2
- RYR2 | c.7404G>T p.M2468I | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV63719573; called by muse, mutect2, varscan2
- SLC22A12 | c.1231G>C p.A411P | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.756); catalogued as COSV60574449; called by muse, mutect2, varscan2
- SNTG2 | c.1277G>A p.R426K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.978); catalogued as rs372191385; called by muse, mutect2, varscan2
- SSH2 | c.1113G>A p.W371* | Nonsense Mutation (SNP) | VAF 12/38 reads (32%) | catalogued as COSV52182827; called by muse, mutect2, varscan2
- TARS1 | c.2078A>G p.N693S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.956); catalogued as rs769530358, COSV54312862; called by muse, mutect2, varscan2
- TBX20 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68783843, COSV68785950; called by muse, mutect2, varscan2
- TCTEX1D2 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV57489599; called by muse, mutect2, varscan2
- TG | c.5922G>A p.M1974I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs774942370, COSV99599880; called by mutect2, varscan2
- VAC14 | c.2086G>C p.A696P | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV55758554; called by muse, mutect2, varscan2
- ZBTB45 | c.1277C>T p.S426L | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV54022440; called by muse, mutect2, varscan2
- ZNF474 | c.475C>T p.Q159* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV56947977; called by muse, mutect2
- ZNF614 | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54548520; called by muse, mutect2, varscan2
- CHD5 | c.93_94dup p.G32Vfs*15 | Frame Shift Ins (INS) | VAF 13/28 reads (46%) | called by mutect2, pindel, varscan2
- TP53BP1 | c.5653del p.L1885Wfs*9 | Frame Shift Del (DEL) | VAF 21/44 reads (48%) | called by mutect2, pindel, varscan2
- C17orf58 | c.36C>T p.F12= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV57817241; called by muse, mutect2, varscan2
- CAPN12 | c.1782C>T p.L594= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs780294054, COSV53151443; called by muse, mutect2, varscan2
- CEP19 | c.491G>A p.*164= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV56361601; called by muse, mutect2, varscan2
- DNAI2 | c.1557G>A p.L519= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1223294262, COSV56758279, COSV56763153; called by muse, mutect2, varscan2
- EHD1 | c.609G>C p.V203= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV57737179; called by muse, mutect2, varscan2
- FEZF2 | c.906C>A p.A302= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV51864789; called by muse, mutect2, varscan2
- GAB3 | c.252C>T p.F84= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs1557257582, COSV65818892; called by muse, mutect2, varscan2
- KIF5B | c.1737A>T p.G579= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV56656794; called by mutect2, varscan2
- LGALS4 | c.594G>A p.L198= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100313139; called by muse, mutect2, varscan2
- PHLPP1 | c.4305C>T p.S1435= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs947939934, COSV53032496; called by muse, mutect2, varscan2
- PNKP | c.1458C>T p.F486= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as rs780614119, COSV55591071; called by muse, mutect2, varscan2
- RFTN2 | c.414C>T p.D138= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs200976367; called by muse, mutect2, varscan2
- SVEP1 | c.7815C>T p.I2605= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as rs1027107416, COSV52844960; called by muse, mutect2, varscan2
